Somatic mutation profile of tumor specimen MP2PRT-PATUHM-TMP1-A (aliquot MP2PRT-PATUHM-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATUHM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.4 years (499 days).
Specimen MP2PRT-PATUHM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55496a15-9796-41b8-a61e-fcb8fd1c6562.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATUHM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATUHM-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12336d89-7068-46a5-9e5d-4090d939076d

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 67/477 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACCSL | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.036); catalogued as rs760949826, COSV66580741; called by muse, mutect2
- ORC4 | c.872C>A p.T291K | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV51576118; called by muse, mutect2, varscan2
- PLS3 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs782676126; called by mutect2, varscan2
- GPRC5D | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 57/262 reads (22%) | called by muse, varscan2
- PDK1 | c.151C>G p.R51G | Missense Mutation (SNP) | VAF 89/759 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
